Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5173, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5173-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

TCGA-BP-5173

Specimens Submitted:

1: SP: Right renal tumor ()

2: SP: Deep margin #2 ()

DIAGNOSIS:

- 1) KIDNEY, RIGHT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 2.0 CM. ✓
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE. ✓
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- THE TUMOR IS LESS THAN 1 MM FROM THE SURGICAL MARGIN.
- THE NON-NEOPLASTIC KIDNEY SHOWS PATCHY LYMPHOCYTIC INFILTRATE. ✓
- THE ADRENAL GLAND IS NOT SUBMITTED.

- 2) FAT, DEEP MARGIN; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section diagnosis, labeled, "Right renal tumor (stitch marks deep margin)". It consists of a 5.0 x 3.5 x 2.5 cm tan-red renal tissue with a 2.0 x 2.0 x 2.0 cm tan-yellow tumor mass. Grossly the tumor mass extends to less than 0.1 cm to the nearest resection margin. Grossly the margin is free. The uninvolved renal cortical tissue is unremarkable. Also received is attached perirenal fat, measuring in aggregate 5.0 x 2.0 x 2.0 cm and is grossly unremarkable. The specimen is representatively submitted.

Summary of Sections:

FSCA - frozen section control A

FSCB - frozen section control B

TU - tumor

R - uninvolved kidney

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

2) The specimen is received fresh for frozen section diagnosis, labeled, "Deep margin #2". It consists of a tan-yellow soft tissue measuring 0.8 x 0.3 x 0.2 cm. Entirely frozen.

Summary of Sections:
FSC – frozen section control

Summary of Sections:

Part 1: SP: Right renal tumor

Block	Sect. Site	PCs
1	fsc	1
1	fscb	1
1	r	1
2	tu	2

Part 2: SP: Deep margin #2

Block	Sect. Site	PCs
1	fsc	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1A-B) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. NEGATIVE RESECTION MARGIN.
PERMANENT DIAGNOSIS: SAME.

2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 74f8c4a8-7776-472b-86a1-b8243538a70d (TCGA-BP-5173.29C4A2EC-B1CC-4E27-B9AC-4A669C01C02C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).